Somatic mutation profile of tumor specimen 0DA2XO from CCDI case PBBJMI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,105 days).
Specimen 0DA2XO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fec49548-f778-4431-b713-c6b1392576eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA2Y6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faf77aeb-c179-4095-b100-80fb426d3f3a

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, Nonsense Mutation 2, Silent 2, Splice Site 1, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRINP3 | c.1184+1G>A p.X395_splice | Splice Site (SNP) | VAF 104/274 reads (38%) | catalogued as COSV100819649; called by muse, mutect2, varscan2
- EGFL7 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 59/757 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as rs374745249; called by muse, mutect2
- MYO7A | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 78/591 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as rs397516282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFAT5 | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 193/450 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs770031844; called by muse, mutect2, varscan2
- PAIP1 | c.326C>A p.S109* | Nonsense Mutation (SNP) | VAF 163/615 reads (27%) | catalogued as COSV100166454; called by muse, mutect2, varscan2
- ANO5 | c.2189G>A p.W730* | Nonsense Mutation (SNP) | VAF 75/431 reads (17%) | called by muse, mutect2, varscan2
- MINK1 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MYCBP2 | c.12188A>G p.N4063S (on ENST00000357337; = p.N4101S on NM_015057.5) | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NDUFS1 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2
- POLK | c.982A>C p.K328Q | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3C | c.625_626del p.L209Vfs*2 | Frame Shift Del (DEL) | VAF 67/346 reads (19%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.14dup p.A6Rfs*61 | Frame Shift Ins (INS) | VAF 93/457 reads (20%) | called by pindel, varscan2
- ZIC1 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 133/579 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM166B | c.394C>T p.L132= | Silent (SNP) | VAF 115/638 reads (18%) | catalogued as COSV63428102; called by muse, mutect2, varscan2
- N4BP3 | c.540C>T p.G180= | Silent (SNP) | VAF 30/341 reads (9%) | catalogued as rs758855387, COSV51061856; called by muse, mutect2
- CARD16 | c.274+874C>G | Intron (SNP) | VAF 13/490 reads (3%) | called by muse, mutect2
- COL17A1 | c.2228-57A>G | Intron (SNP) | VAF 33/281 reads (12%) | called by muse, mutect2, varscan2
- DDX51 | c.1441-45C>G | Intron (SNP) | VAF 30/365 reads (8%) | called by muse, mutect2
- KRT37 | c.*22G>T | 3'UTR (SNP) | VAF 156/422 reads (37%) | called by muse, mutect2, varscan2
- TMEM208 | c.-63G>A | 5'UTR (SNP) | VAF 29/308 reads (9%) | called by muse, mutect2
